CCDI case PBCFMH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c9ae8fd7-beae-4ff5-8040-5da40971d83c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.3 years (9,243 days).

Biospecimens (1 sample)
- Sample 0DQVIF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
